Somatic mutation profile of tumor specimen ALCH-B4C4-TTP1-B (aliquot ALCH-B4C4-TTP1-B-1-0-D-A80E-36) from ALCHEMIST case ALCH-B4C4, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 76.6 years (27,968 days).
Specimen ALCH-B4C4-TTP1-B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0ff52e81-155c-4d59-8cc5-21133bfb10a8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B4C4-NB1-A (Blood Derived Normal), aliquot ALCH-B4C4-NB1-A-1-0-D-A80E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a28e7dad-60e5-4746-ab62-a61f6de67a3a

The open-access MAF lists 41 somatic variants for this specimen: 25 protein-altering or splice-affecting, 12 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 12, Intron 2, Nonsense Mutation 2, 5'UTR 1, 5'Flank 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD20A4P | c.2329G>A p.V777M | Missense Mutation (SNP) | VAF 34/327 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs562669032, COSV62004811; called by muse, varscan2
- BRINP3 | c.2084C>A p.S695Y | Missense Mutation (SNP) | VAF 16/406 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as COSV66515565; called by muse, mutect2
- CEL | c.1337G>A p.R446Q (on ENST00000673714; = p.R443Q on NM_001807.6) | Missense Mutation (SNP) | VAF 45/494 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.161); catalogued as rs369669750; called by muse, mutect2
- CSMD3 | c.7876G>T p.A2626S (on ENST00000297405 / NM_001363185.1; = p.A2522S on NM_052900.3) | Missense Mutation (SNP) | VAF 22/341 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as rs540447418; called by muse, mutect2
- ENPP1 | c.844C>T p.P282S | Missense Mutation (SNP) | VAF 12/244 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.871); catalogued as COSV100719680; called by muse, mutect2
- GABRG2 | c.1513C>A p.L505I (on ENST00000361925 / NM_001375343.1; = p.L465I on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/780 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV100729734; called by muse, mutect2
- KCNQ5 | c.912G>T p.W304C | Missense Mutation (SNP) | VAF 18/176 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.887); catalogued as COSV59661927; called by muse, mutect2
- LRP1 | c.4774G>T p.E1592* | Nonsense Mutation (SNP) | VAF 32/404 reads (8%) | catalogued as rs1555184879; called by muse, mutect2
- LRP1B | c.581A>T p.K194M | Missense Mutation (SNP) | VAF 56/814 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV101261690; called by muse, mutect2
- MUC12 | c.4492A>G p.T1498A (on ENST00000379442; = p.T1355A on NM_001164462.1) | Missense Mutation (SNP) | VAF 72/1166 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.224); catalogued as rs201323923; called by muse, mutect2
- FAT3 | c.10997T>A p.M3666K | Missense Mutation (SNP) | VAF 13/300 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.262); called by muse, mutect2
- GABRG2 | c.1512C>A p.Y504* (on ENST00000361925 / NM_001375343.1; = p.Y464* on NM_000816.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 34/780 reads (4%) | called by muse, mutect2
- GDF5 | c.635A>T p.D212V | Missense Mutation (SNP) | VAF 23/248 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2
- GLRA2 | c.1012G>T p.V338L | Missense Mutation (SNP) | VAF 29/829 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2
- LARP4B | c.622G>T p.D208Y | Missense Mutation (SNP) | VAF 28/632 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- MYB | c.1001A>G p.D334G | Missense Mutation (SNP) | VAF 52/742 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.076); called by muse, mutect2
- NBAS | c.6234G>A p.K2078= | Splice Region (SNP) | VAF 44/941 reads (5%) | called by muse, mutect2
- NHS | c.3911C>G p.S1304C | Missense Mutation (SNP) | VAF 31/1104 reads (3%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.24); called by muse, mutect2
- OTUD7A | c.1228G>A p.D410N (on ENST00000307050 / NM_001382637.1; = p.D403N on NM_130901.3) | Missense Mutation (SNP) | VAF 14/338 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- PTPRZ1 | c.5354C>A p.A1785D | Missense Mutation (SNP) | VAF 18/281 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SYK | c.718-1G>T p.X240_splice | Splice Site (SNP) | VAF 24/271 reads (9%) | called by muse, mutect2
- TEX47 | c.673G>T p.D225Y | Missense Mutation (SNP) | VAF 20/326 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); called by muse, mutect2
- TRIM46 | c.196T>A p.Y66N | Missense Mutation (SNP) | VAF 18/381 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.739); called by muse, mutect2
- UNC79 | c.6229G>T p.V2077L (on ENST00000393151 / NM_001346218.2; = p.V1900L on NM_020818.5) | Missense Mutation (SNP) | VAF 16/418 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2
- ZDHHC9 | c.1026C>A p.S342R | Missense Mutation (SNP) | VAF 30/737 reads (4%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.011); called by muse, mutect2
- ABCB1 | c.3762T>C p.H1254= | Silent (SNP) | VAF 92/2201 reads (4%) | catalogued as rs1404008939; called by muse, mutect2
- KCNQ2 | c.2445T>C p.D815= (on ENST00000359125 / NM_172107.4; = p.D787= on NM_004518.6) | Silent (SNP) | VAF 62/758 reads (8%) | called by muse, mutect2
- KCNQ2 | c.2058T>C p.I686= (on ENST00000359125 / NM_172107.4; = p.I658= on NM_004518.6) | Silent (SNP) | VAF 21/268 reads (8%) | catalogued as rs1402049640; called by muse, mutect2
- KRTAP10-7 | c.972C>T p.P324= | Silent (SNP) | VAF 13/365 reads (4%) | catalogued as rs587761339; called by muse, mutect2
- LARP4B | c.621G>T p.V207= | Silent (SNP) | VAF 28/635 reads (4%) | called by muse, mutect2
- PAXBP1 | c.420A>G p.K140= | Silent (SNP) | VAF 10/145 reads (7%) | called by muse, mutect2
- PRPF8 | c.5808C>G p.L1936= | Silent (SNP) | VAF 49/678 reads (7%) | called by muse, mutect2
- PSME1 | c.492C>T p.H164= | Silent (SNP) | VAF 29/570 reads (5%) | called by muse, mutect2
- SFTPC | c.25C>T p.L9= | Silent (SNP) | VAF 96/1370 reads (7%) | called by muse, mutect2
- TBC1D22B | c.1314C>T p.S438= | Silent (SNP) | VAF 42/690 reads (6%) | called by muse, mutect2
- TESMIN | c.1083T>C p.N361= | Silent (SNP) | VAF 22/644 reads (3%) | called by muse, mutect2
- TLE4 | c.1317G>T p.L439= | Silent (SNP) | VAF 24/572 reads (4%) | called by muse, mutect2
- AC244517.10 | c.36-8776G>C | Intron (SNP) | VAF 41/594 reads (7%) | called by muse, mutect2
- C1orf122 | c.-224C>A | 5'UTR (SNP) | VAF 8/199 reads (4%) | called by muse, mutect2
- COL11A1 | c.3168+51C>T | Intron (SNP) | VAF 26/428 reads (6%) | called by muse, mutect2
- RNA5S17 | chr1:228650524 C>A | 5'Flank (SNP) | VAF 36/708 reads (5%) | called by muse, mutect2
